Somatic mutation profile of tumor specimen TCGA-DD-AAD5-01A (aliquot TCGA-DD-AAD5-01A-11D-A40R-10) from TCGA case TCGA-DD-AAD5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.1 years (19,748 days).
Specimen TCGA-DD-AAD5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eae985f-d994-4a96-9c71-3ab13a5b4295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAD5-10A (Blood Derived Normal), aliquot TCGA-DD-AAD5-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bb79380-7e58-407c-84ff-bba959425794

The open-access MAF lists 144 somatic variants for this specimen: 106 protein-altering or splice-affecting, 37 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 37, Frame Shift Del 9, Nonsense Mutation 5, Frame Shift Ins 5, Splice Site 4, Nonstop Mutation 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM9 | c.2101G>A p.V701I | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.194); catalogued as COSV101166203; called by muse, mutect2, varscan2
- ADGRF3 | c.1454C>A p.A485D (on ENST00000311519 / NM_001145168.1; = p.A286D on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1196602063, COSV100275242; called by muse, mutect2, varscan2
- AKR1C4 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 108/180 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs373855442; called by muse, mutect2, varscan2
- ATF4 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.112); catalogued as rs372679887, COSV100307773; called by muse, mutect2, varscan2
- B4GAT1 | c.827T>A p.V276E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100240342; called by muse, mutect2, varscan2
- BRD7 | c.1363T>A p.Y455N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101165023; called by muse, varscan2
- C8A | c.32T>A p.L11* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as COSV100776608; called by muse, mutect2, varscan2
- CACNA1G | c.5545G>A p.V1849M | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100662215; called by muse, mutect2, varscan2
- CCDC144A | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 95/187 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as COSV100138629; called by muse, mutect2, varscan2
- CCDC185 | c.1501A>T p.M501L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100838819, COSV64821212; called by muse, mutect2
- CCDC88B | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100105684; called by muse, mutect2, varscan2
- CEP350 | c.3484T>A p.S1162T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV100854999; called by muse, mutect2, varscan2
- CEP63 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.168); catalogued as rs1553789251, COSV59675765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CKAP2 | c.1460C>G p.A487G (on ENST00000378037 / NM_001098525.2; = p.A486G on NM_018204.5) | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV99318397; called by muse, mutect2, varscan2
- CSE1L | c.237T>G p.D79E | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); catalogued as COSV99522130; called by muse, mutect2, varscan2
- CYP2A6 | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV56533680; called by muse, mutect2
- EHBP1 | c.2663A>G p.Y888C | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as rs750382472, COSV99861436; called by muse, mutect2, varscan2
- EIF5B | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 137/437 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); catalogued as COSV99177563; called by muse, mutect2, varscan2
- ESYT3 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100004894; called by muse, mutect2, varscan2
- F13A1 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV99343573; called by muse, mutect2, varscan2
- FOXC1 | c.902C>G p.P301R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101083333; called by muse, mutect2, varscan2
- GBA2 | c.2047_2048insC p.G683Afs*32 | Frame Shift Ins (INS) | VAF 22/63 reads (35%) | catalogued as COSV100803450; called by mutect2, pindel, varscan2
- GFM1 | c.1914G>C p.L638F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51832705, COSV99963046; called by muse, mutect2, varscan2
- GJA8 | c.276C>A p.Y92* | Nonsense Mutation (SNP) | VAF 54/76 reads (71%) | catalogued as COSV53790852, COSV99569566; called by muse, mutect2, varscan2
- HS3ST1 | c.331T>A p.W111R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV99136905; called by muse, mutect2, varscan2
- HS3ST6 | c.742A>G p.S248G | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99562801; called by muse, mutect2, varscan2
- IFNGR2 | c.832A>C p.K278Q | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99274791; called by muse, mutect2, varscan2
- IGSF10 | c.5905C>T p.P1969S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227027161, COSV56786680; called by muse, mutect2, varscan2
- IGSF9B | c.1535C>A p.A512D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100318103; called by mutect2, varscan2
- JAK1 | c.2185A>T p.S729C | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV61087444; called by muse, mutect2, varscan2
- KANSL1 | c.2581A>G p.I861V (on ENST00000574590 / NM_001193465.2; = p.I862V on NM_015443.4) | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV99294736; called by muse, mutect2, varscan2
- KCNA10 | c.1495A>G p.K499E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.079); catalogued as rs778569816, COSV100871462; called by muse, mutect2, varscan2
- KIFC3 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101109286; called by muse, mutect2, varscan2
- LAT | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100611521; called by muse, mutect2, varscan2
- LHX6 | c.155T>C p.V52A (on ENST00000373755 / NM_001242334.2; = p.V81A on NM_014368.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as COSV100493539; called by muse, mutect2, varscan2
- LRRC74A | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99372591; called by muse, mutect2, varscan2
- LYPLA1 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV100387375; called by muse, mutect2, varscan2
- MED12 | c.2774G>T p.C925F | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100379113; called by muse, mutect2, varscan2
- NEUROD4 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99670002; called by muse, mutect2, varscan2
- NMRK2 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as COSV99396416; called by muse, mutect2
- NUDT6 | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 201/513 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV99144690; called by muse, mutect2, varscan2
- NUMA1 | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs754504305, COSV100706411; called by muse, mutect2, varscan2
- OBSCN | c.7513G>A p.D2505N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.921); catalogued as rs1382086607, COSV99482052; called by muse, mutect2
- OXSM | c.1205G>C p.C402S | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99772074; called by muse, mutect2, varscan2
- PCDH7 | c.951G>T p.L317F | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100688521; called by muse, mutect2, varscan2
- PCDHA13 | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99167736; called by muse, mutect2, varscan2
- PCID2 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV99872579; called by muse, mutect2, varscan2
- PGM2L1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99995064; called by muse, mutect2, varscan2
- PLCD1 | c.2263C>T p.Q755* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | catalogued as COSV99379093, COSV99379367; called by muse, mutect2, varscan2
- PLXNA1 | c.3544G>T p.G1182C | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52523238, COSV99303700; called by muse, mutect2, varscan2
- PLXNA4 | c.4387T>G p.C1463G | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100325861; called by muse, mutect2, varscan2
- POLR1C | c.249+1G>T p.X83_splice | Splice Site (SNP) | VAF 39/113 reads (35%) | catalogued as COSV99541203; called by muse, mutect2, varscan2
- PTPN12 | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs780590972, COSV99950558; called by muse, mutect2, varscan2
- PTPN5 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV100659949; called by muse, mutect2, varscan2
- PTPRB | c.680C>G p.T227S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.347); catalogued as rs1477501709, COSV100547616; called by muse, mutect2, varscan2
- RCC1 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268238503, COSV100868167; called by muse, mutect2, varscan2
- RNF44 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99221956; called by muse, mutect2, varscan2
- RYR1 | c.8267A>G p.N2756S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100616427; called by muse, mutect2, varscan2
- RYR1 | c.8624C>A p.A2875E | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100616429; called by muse, mutect2, varscan2
- SAMD9L | c.4547dup p.N1516Kfs*2 | Frame Shift Ins (INS) | VAF 34/107 reads (32%) | catalogued as rs776688287; called by mutect2, varscan2
- SEC23IP | c.1855C>G p.H619D | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100956978; called by muse, mutect2, varscan2
- SEPTIN10 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100454214, COSV61780537; called by muse, mutect2, varscan2
- SLC13A4 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100647315; called by muse, mutect2, varscan2
- SLC22A23 | c.1993C>A p.H665N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV100978330; called by muse, mutect2
- SLFN11 | c.2229A>T p.K743N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100390839; called by muse, mutect2, varscan2
- SNRNP27 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.728); catalogued as COSV99732192; called by muse, mutect2, varscan2
- SNX4 | c.727-1G>T p.X243_splice | Splice Site (SNP) | VAF 129/419 reads (31%) | catalogued as COSV99305165; called by muse, mutect2, varscan2
- SPATA20 | c.2288A>G p.Y763C (on ENST00000356488 / NM_001258372.1; = p.Y779C on NM_022827.4) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1223677208, COSV99136359; called by muse, mutect2, varscan2
- SQSTM1 | c.991T>A p.C331S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV99481678; called by muse, mutect2, varscan2
- STK10 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938760232, COSV51575546; called by muse, mutect2, varscan2
- STOX1 | c.2681G>C p.R894T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs1254413218, COSV100058096; called by muse, mutect2, varscan2
- STXBP3 | c.1778A>G p.*593Wext*16 | Nonstop Mutation (SNP) | VAF 35/84 reads (42%) | catalogued as COSV100894041; called by muse, mutect2, varscan2
- TAOK2 | c.3104G>T p.R1035L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV99663224; called by muse, mutect2, varscan2
- TCF25 | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV99643208; called by muse, mutect2, varscan2
- TCHH | c.5056C>T p.R1686C | Missense Mutation (SNP) | VAF 98/135 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV64274827; called by muse, mutect2, varscan2
- TMC1 | c.1330G>C p.G444R | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as CM094818, COSV99920074; called by muse, mutect2, varscan2
- TP53 | c.1021T>G p.F341V | Missense Mutation (SNP) | VAF 70/102 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV53651123, COSV99427375; called by muse, mutect2, varscan2
- TRIM42 | c.1873T>C p.C625R | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53887938; called by muse, mutect2, varscan2
- TRPC6 | c.1761C>A p.D587E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.475); catalogued as rs747089189, COSV100723716; called by muse, mutect2, varscan2
- VCPIP1 | c.1145A>G p.Q382R | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100125730; called by muse, mutect2, varscan2
- VPS13B | c.598A>T p.R200* | Nonsense Mutation (SNP) | VAF 92/369 reads (25%) | catalogued as COSV100662773; called by muse, mutect2, varscan2
- ZBED1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV100585856, COSV58139620; called by muse, mutect2, varscan2
- ZFPM2 | c.911C>G p.T304S | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.388); catalogued as COSV101023329, COSV65874406; called by muse, mutect2
- ZIC2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775296747, COSV100891803; called by muse, mutect2, varscan2
- ZNF250 | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99480973; called by muse, mutect2, varscan2
- ZNF318 | c.4448C>T p.S1483F | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as COSV100546390; called by muse, mutect2, varscan2
- ZNF568 | c.894A>T p.R298S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100451366; called by muse, mutect2, varscan2
- ZNF638 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1207073357, COSV100039436; called by muse, mutect2, varscan2
- ZNF831 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV100926147; called by muse, mutect2, varscan2
- ZNF92 | c.1627G>A p.D543N (on ENST00000328747 / NM_152626.4; = p.D474N on NM_007139.4) | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100165908; called by muse, mutect2, varscan2
- AKNA | c.2812_2837del p.T938Pfs*81 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel
- ANKRD13A | c.872dup p.R292Efs*3 | Frame Shift Ins (INS) | VAF 57/165 reads (35%) | called by mutect2, varscan2
- ECT2 | c.753_756del p.E252Rfs*24 (on ENST00000392692 / NM_001349098.2; = p.E221Rfs*24 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 66/150 reads (44%) | called by mutect2, pindel, varscan2
- GCDH | c.514dup p.E172Gfs*16 | Frame Shift Ins (INS) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- HCFC2 | c.741del p.H248Ifs*6 | Frame Shift Del (DEL) | VAF 35/123 reads (28%) | called by mutect2, pindel, varscan2
- ICE1 | c.3395dup p.N1132Kfs*29 | Frame Shift Ins (INS) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- IGHV3-20 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KDM3A | c.3885_3885+12del p.X1295_splice | Splice Site (DEL) | VAF 18/91 reads (20%) | called by pindel, varscan2
- MAPK9 | c.152_153del p.N51Sfs*22 | Frame Shift Del (DEL) | VAF 29/163 reads (18%) | called by mutect2, pindel, varscan2
- MYO15A | c.340_361del p.R114Gfs*323 | Frame Shift Del (DEL) | VAF 61/117 reads (52%) | called by mutect2, pindel, varscan2
- PKHD1 | c.10837_10841del p.D3613* | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | called by mutect2, pindel, varscan2
- POP1 | c.487-11_487-1del p.X163_splice | Splice Site (DEL) | VAF 27/230 reads (12%) | called by mutect2, pindel, varscan2
- PPFIBP2 | c.751_774del p.D251_H258del | In Frame Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- SYNJ1 | c.1412_1440delinsT p.N471Mfs*12 | Frame Shift Del (DEL) | VAF 48/135 reads (36%) | called by pindel, varscan2*
- TMEM62 | c.1065del p.K356Rfs*7 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- TTF1 | c.62del p.K21Sfs*23 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- ABCA4 | c.2229C>T p.A743= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV100933173; called by muse, mutect2, varscan2
- ARID1A | c.2646G>C p.G882= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as rs149901342; called by muse, mutect2, varscan2
- ATL1 | c.648T>C p.V216= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV100613215; called by muse, mutect2, varscan2
- C2orf15 | c.174A>G p.T58= | Silent (SNP) | VAF 112/392 reads (29%) | catalogued as rs1162660988, COSV100209029; called by muse, mutect2, varscan2
- C8orf34 | c.1221C>T p.N407= | Silent (SNP) | VAF 69/137 reads (50%) | catalogued as COSV100298790; called by muse, mutect2, varscan2
- CACNA1E | c.3297G>A p.L1099= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as COSV100704222; called by muse, mutect2, varscan2
- CACNA1G | c.1854C>T p.T618= | Silent (SNP) | VAF 99/331 reads (30%) | catalogued as COSV100662213; called by muse, mutect2, varscan2
- CCKBR | c.519C>T p.R173= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1054148069, COSV100583042; called by muse, mutect2, varscan2
- CDH2 | c.559A>C p.R187= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99297706; called by muse, mutect2, varscan2
- CENPM | c.306A>G p.T102= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV99317902; called by muse, mutect2, varscan2
- CHD9 | c.4731T>A p.P1577= | Silent (SNP) | VAF 111/343 reads (32%) | catalogued as COSV99529471; called by muse, mutect2, varscan2
- CIC | c.3066G>A p.A1022= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs774714572, COSV50548005; called by muse, varscan2
- DOP1B | c.3327C>T p.H1109= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs981738604, COSV101215658; called by muse, mutect2, varscan2
- EGR1 | c.6C>G p.A2= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99525527; called by muse, varscan2
- EPHA10 | c.252G>A p.Q84= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV100140052; called by muse, mutect2, varscan2
- FAM171A1 | c.1155C>G p.P385= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as rs143895945, COSV100968384; called by muse, mutect2, varscan2
- FAT1 | c.6228T>C p.D2076= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV101499490; called by muse, mutect2, varscan2
- FZD5 | c.357G>A p.L119= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99776457; called by muse, mutect2, varscan2
- HAL | c.801A>G p.L267= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV99701566; called by muse, mutect2, varscan2
- HAPLN1 | c.756T>C p.C252= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV99165090; called by muse, mutect2, varscan2
- KCNE3 | c.12C>T p.T4= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV100035672; called by muse, mutect2, varscan2
- KL | c.1377C>G p.S459= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV101199162, COSV66309613; called by muse, mutect2, varscan2
- MICAL3 | c.2736G>A p.E912= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99262423; called by muse, mutect2, varscan2
- MIER3 | c.393G>T p.V131= | Silent (SNP) | VAF 89/172 reads (52%) | catalogued as COSV100423561; called by muse, mutect2, varscan2
- NRXN1 | c.79C>T p.L27= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV101278300, COSV68052269; called by muse, mutect2, varscan2
- PALLD | c.2142T>C p.G714= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99825361; called by muse, mutect2, varscan2
- PGS1 | c.1533G>A p.L511= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV99428396; called by muse, mutect2, varscan2
- RNF17 | c.3765C>T p.G1255= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs180999676, COSV55033256; called by muse, mutect2, varscan2
- SLC22A23 | c.1995C>T p.H665= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1194584346, COSV100978329; called by muse, mutect2
- SLC35G1 | c.801C>T p.V267= (on ENST00000427197 / NM_001134658.3; = p.V266= on NM_153226.4) | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV101004097; called by muse, mutect2, varscan2
- TTLL10 | c.1104G>A p.P368= (on ENST00000379289 / NM_001130045.2; = p.P295= on NM_153254.3) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs371622937; called by muse, mutect2, varscan2
- TTN | c.17793C>T p.T5931= (on ENST00000591111; = p.T5004= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs775965000, COSV100622099; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR5B | c.633T>C p.P211= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV99216420; called by muse, mutect2, varscan2
- ZFHX4 | c.9288A>T p.T3096= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV99265560; called by muse, mutect2, varscan2
- ZFP64 | c.240T>G p.T80= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV99402818; called by muse, mutect2, varscan2
- ZNF430 | c.153C>T p.C51= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV99841910; called by muse, mutect2, varscan2
- ZNF485 | c.390T>C p.Y130= | Silent (SNP) | VAF 97/195 reads (50%) | catalogued as COSV100700256; called by muse, mutect2, varscan2
- SSPOP | n.6372T>G | RNA (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100022767; called by muse, mutect2, varscan2
